Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5728, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5728-01A (Primary Tumor).

*** Diagnosis(es): ***

Total gastrectomy specimen including an extensively ulcerated, weakly differentiated adenocarcinoma (intestinal type under Lauren's classification) of maximum diameter 7.5 cm located in the antrum with infiltration of the perimuscular or subserosal soft tissue and evidence of lymphatic invasion. Tumor-free regional lymph nodes. Free-free oral and aboral resection margin. Free-free omental fatty tissue.

Free stage: pT2b pN0 (0/36) pMX; [REDACTED]

Source: NCI Genomic Data Commons file 2a685164-7701-44de-86a7-614892106b1f (TCGA-CG-5728.E0ACEEA3-18B5-4206-8D11-FC93B6E1949E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).